Surgical pathology report (de-identified scan), TCGA case TCGA-30-1862, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Harvard, specimen TCGA-30-1862-01A (Primary Tumor).

[page 1 of 3]
Accession Number: [REDACTED]
Type: Surgical Pathology
Pathology Report: [REDACTED] MUSCLE BIOPSY
Accessioned On: [REDACTED]

Report Status: Final

TCGA-30-1862

DIAGNOSIS:

SPECIMEN LABELED "OMENTAL TUMOR MASS" (including FSA):
PAPILLARY SEROUS ADENOCARCINOMA (3.2 cm).

SPECIMEN LABELED "TUMOR FROM STOMACH":
PAPILLARY SEROUS ADENOCARCINOMA (3.2 cm).

SPECIMEN LABELED "RIGHT TUBE AND OVARY":
PAPILLARY SEROUS ADENOCARCINOMA grade 2 of 3 involving surface of ovary
and fallopian tube, and minimally invading ovarian parenchyma.
Peritubal adhesions.

SPECIMEN LABELED "LEFT TUBE AND OVARY":
PAPILLARY SEROUS ADENOCARCINOMA involving surface of ovary and fallopian
tube.

SPECIMEN LABELED "CUL DE SAC TUMOR":
PAPILLARY SEROUS ADENOCARCINOMA.

SPECIMEN LABELED "UTERUS AND CERVIX" (98g):
Cervix:
Squamous metaplasia.

Endometrium:
Inactive endometrium.
Endometrial polyps.

Myometrium:
Leiomyomata
Adenomyosis.

Serosa:
PAPILLARY SEROUS ADENOCARCINOMA.

SPECIMEN LABELED "CUL DE SAC TUMOR II":
PAPILLARY SEROUS ADENOCARCINOMA.

SPECIMEN LABELED "TUMOR ON APPENDIX":
PAPILLARY SEROUS ADENOCARCINOMA.

SPECIMEN LABELED "APPENDIX AND TUMOR":
PAPILLARY SEROUS ADENOCARCINOMA.

SPECIMEN LABELED "UMBILICAL HERNIA":
Fibroadipose tissue with acute and chronic inflammation.

Note: The tumor distribution favors a PRIMARY PERITONEAL SEROUS CARCINOMA.

CLINICAL DATA:

History: [REDACTED] - CA125 1500, ascites, omental cake, ?ovarian
cancer.

Clinical Diagnosis: Ascites

TISSUE SUBMITTED: 1. Rectal muscles to research
2. Omental tumor mass (FS)
3. Tumor from stomach
4. Right tube and ovary
5. Left tube and ovary
6. Cul de sac tumor
7. Uterus and cervix

[page 2 of 3]
8. Cul de sac tumor II
9. Tumor on appendix
10. Appendix and tumor
11. Umbilical hernia sac

TCGA-30-1862

O.R. CONSULTATION:

SPECIMEN LABELED "#2 OMENTAL TUMOR MASS" (FSA):

Poorly differentiated carcinoma, consistent with ovarian origin.

GROSS DESCRIPTION:

The specimen is received fresh, in 11 parts, each labeled with the patient's name and unit number.

Part 1, "rectus muscles", consists of one fragment of red/tan/brown soft tissue (2.5 x 2.3 x 1.5 cm) grossly consistent with skeletal muscle. The entire specimen is submitted for special studies.

Part 2, "omental tumor mass - FS", consists of one fragment of yellow/tan/pink fibroadipose tissue (34 x 8 x 4 cm) with multiple firm, yellow/white nodules (up to 6 cm). A representative section of one nodule is frozen and submitted as "FSA". Representative nodules are submitted for special studies and tumor bank. Some of the nodules have areas of hemorrhage and necrosis. Representative sections are submitted.

Micro 1 - FSA remnant, 1 frag, [REDACTED]
Micro 2 - omental tumor mass, 1 frag, [REDACTED]

Part 3, "tumor from stomach", consists of a 5 x 4 x 4 cm fragment of yellow/tan/white fibroadipose tissue with a 3.2 x 3 x 1.6 cm firm, white/tan, ill-defined mass. Representative sections are submitted.

Micro 3 - tumor from stomach, 3 frags, [REDACTED]

Part 4, "right tube and ovary", consists of a 5.3 x 4.0 x 1.9 cm ovary and fallopian tube. The fallopian tube (approximately 5.8 x 1.1 cm) has areas of edema and adhesions to a 3.1 x 1.6 x 1.4 cm ovary. There are multiple papillary excrescences in the adnexal tissue. Representative sections are submitted.

Micro 4-6 - right tube and ovary, 1-2 frags each, [REDACTED]

Part 5, "left tube and ovary", consists of a 5.0 x 1.0 cm fimbriated edematous fallopian tube, a 2.6 x 1.4 x 1.3 cm ovary and associated adnexal tissue. The ovary has a yellow/white, slightly rough, nodular surface. There are multiple tan, papillary excrescences (up to 0.4 cm) throughout the adnexa. Representative sections are submitted.

Micro 7-9 - left tube and ovary, 1-2 frags each, [REDACTED]

Part 6, "cul de sac tumor", consists of multiple fragments of firm, yellow/white, hemorrhagic tissue (6 x 5 x 2 cm in aggregate). Representative sections are submitted.

Micro 10-11 - cul de sac tumor, 3 frags each, [REDACTED]

Part 7, "uterus and cervix", consists of a 98g hysterectomy specimen (9 x 6 x 4 cm in overall dimensions) which has a rough, nodular, focally hemorrhagic serosal surface and a subserosal leiomyoma (2 cm). The exocervix (3.1 cm in diameter) has a 0.7 cm slit-like os leading to a 2.4 x 1.0 cm endocervical canal. The endocervix has a tan, glistening herringbone-like appearance. The endometrium (4.4 cm from cornu to cornu, 4.5 cm in length and 0.2 cm in thickness) is tan and glistening with multiple polyps (from 0.1 to 2.5 cm). The myometrium (1.3 cm in average thickness) has an intramural leiomyoma (0.6 cm). Representative sections are submitted.

Micro 12 - anterior cervix, 1 frag, [REDACTED]
Micro 13 - posterior cervix, 1 frag, [REDACTED]
Micro 14 - LUS, 1 frag, [REDACTED]
Micro 15-16 - anterior endometrium, serosal nodules & polyps, 1-2 frags each, [REDACTED]
Micro 17 - posterior endometrium, polyps & leiomas, 1 frag each, [REDACTED]

[page 3 of 3]
*Part 8, "cul de sac tumor II", consists of two fragments of white/tan/yellow soft tissue with a papillary, friable texture (in aggregate 5 x 4.2 x 2.1 cm). Representative sections are submitted.

Micro 19 - cul de sac tumor II, 3 frags, [REDACTED]

Part 9, "tumor on appendix", consists of a 2.1 x 1.1 x 1.1 cm fragment of white/tan, papillary appearing, firm tissue. Representative sections are submitted.

TCGA-30-1862

Micro 20 - tumor on appendix, 2 frags, [REDACTED]

Part 10, "appendix and tumor", consists of a 4.5 x 3 x 2.1 cm multiloculated cystic mass filled with green and tan mucinous fluid. Near the re-section margin is a 1 x 1 x 1 cm area of white/tan, nodular, firm tissue. The resection margin of the appendix is 0.6 cm in diameter and has an obliterated lumen. Representative sections are submitted.

Micro 21 - resection margin & possible tip, 2 frags, [REDACTED]

Micro 22 - appendix & tumor, 3 frags, [REDACTED]

Part 11, "umbilical hernia sac", consists of a 3.9 x 2.6 x 0.7 cm fragment of yellow/tan, hemorrhagic soft tissue. Representative sections are submitted.

Micro 23 - umbilical hernia sac, 3 frags, [REDACTED]

Reports to: [REDACTED]

SPECIMEN TYPE: MUSCLE BIOPSY

ADDITIONAL SPECIMEN TYPE: SOFT TISSUE TUMOR EXTENSIVE RESECTION

ADDITIONAL SPECIMEN TYPE: SOFT TISSUE MASS OR SIMPLE EXCISION

ADDITIONAL SPECIMEN TYPE: UTERUS WITH OR WITHOUT TUBES & OVARIES, NEOPLASTIC

ADDITIONAL SPECIMEN TYPE: SOFT TISSUE MASS OR SIMPLE EXCISION

ADDITIONAL SPECIMEN TYPE: SOFT TISSUE BIOPSY

ADDITIONAL SPECIMEN TYPE: SOFT TISSUE BIOPSY

ADDITIONAL SPECIMEN TYPE: APPENDIX, OTHER THAN INCIDENTAL

ADDITIONAL SPECIMEN TYPE: HERNIA SAC (ANY LOCATION)

Source: NCI Genomic Data Commons file f87167cd-f3f8-4ed3-bd65-4e0d0d94d5f0 (TCGA-30-1862.A6B7B0C1-5954-487B-B27D-73850A08A194.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).